FM case AD14330 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/3b2b22ea-aeda-4921-b0f1-bea10d723bdb

Male, 50.8 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
